Somatic mutation profile of tumor specimen TCGA-WK-A8XS-01A (aliquot TCGA-WK-A8XS-01A-11D-A37C-09) from TCGA case TCGA-WK-A8XS, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 58.9 years (21,521 days).
Specimen TCGA-WK-A8XS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 570e8ac0-cf0b-4129-ae96-7fdee994ac4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WK-A8XS-10E (Blood Derived Normal), aliquot TCGA-WK-A8XS-10E-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68ac173b-c635-4cf0-9f50-984cb7d71e86

The open-access MAF lists 43 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 10, Intron 2, In Frame Del 1, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN2A | c.2695G>A p.G899S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796053120, COSV51839772; ClinVar: likely pathogenic; called by muse, mutect2
- ADGRF3 | c.1438G>A p.D480N (on ENST00000311519 / NM_001145168.1; = p.D281N on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100275555; called by muse, mutect2, varscan2
- C11orf49 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV99562316, COSV99562997; called by muse, mutect2, varscan2
- CNGB3 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs765866760, COSV100183334; called by muse, mutect2, varscan2
- CUL1 | c.1900G>C p.D634H | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV100296995; called by muse, mutect2, varscan2
- DRAM1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99315900; called by muse, mutect2, varscan2
- GPHB5 | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322724706, COSV100030268; called by muse, mutect2, varscan2
- H2AX | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.23); catalogued as COSV99598259; called by muse, mutect2
- HEPACAM2 | c.80-6C>A | Splice Region (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100506862; called by muse, mutect2
- INPPL1 | c.1682A>T p.H561L | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV99996772; called by muse, mutect2, varscan2
- MAP2K2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as rs757240576, COSV99502866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARS1 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as rs754622037, COSV100007785; called by muse, mutect2, varscan2
- MYO6 | c.2822A>C p.E941A | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100889446; called by muse, mutect2, varscan2
- NUP188 | c.1613G>A p.S538N | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV101001536; called by muse, mutect2, varscan2
- OR13G1 | c.370T>C p.C124R | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100687632, COSV62944769; called by muse, mutect2, varscan2
- OR4S1 | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV100180380; called by muse, mutect2, varscan2
- PHF6 | c.330T>A p.H110Q | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV100136956; called by muse, mutect2, varscan2
- PHKB | c.2327A>C p.Q776P | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV100068930; called by muse, mutect2
- PNMA3 | c.715G>C p.V239L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV100937690; called by muse, mutect2, varscan2
- PPP1R3A | c.2647A>T p.R883W | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV99494743; called by muse, mutect2, varscan2
- PUS7 | c.629C>G p.A210G | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV100708683; called by muse, mutect2, varscan2
- RASAL2 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100863002; called by muse, mutect2, varscan2
- SLAMF8 | c.308T>A p.V103E | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as COSV99223145; called by muse, mutect2, varscan2
- SLC4A7 | c.1661A>G p.N554S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as rs370056312; called by muse, mutect2, varscan2
- SRRM2 | c.1571G>C p.R524T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV100071656; called by muse, mutect2, varscan2
- THOC2 | c.2745C>A p.D915E | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV99834464; called by muse, mutect2
- TRIM26 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT tolerated (0.14); PolyPhen benign (0.214); catalogued as COSV101443994; called by muse, mutect2, varscan2
- ZW10 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99563002; called by muse, mutect2, varscan2
- ITPRID1 | c.2207_2215del p.E736_T738del | In Frame Del (DEL) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- KANK2 | c.1027dup p.A343Gfs*30 | Frame Shift Ins (INS) | VAF 5/33 reads (15%) | called by mutect2, varscan2
- PTEN | c.1007_1011del p.Y336Ffs*5 | Frame Shift Del (DEL) | VAF 21/24 reads (88%) | called by mutect2, pindel, varscan2
- AGBL1 | c.2109C>T p.G703= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs770510450, COSV101224419; called by muse, mutect2, varscan2
- AGK | c.460C>T p.L154= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV100814573; called by muse, mutect2, varscan2
- BAZ1B | c.4416C>A p.A1472= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100290240, COSV59989406; called by muse, mutect2, varscan2
- CDH4 | c.342C>T p.D114= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs776377387, COSV64670683; called by muse, varscan2
- DCT | c.84C>G p.V28= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100986329; called by muse, mutect2
- IGKV2-30 | c.156T>C p.S52= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs915484039; called by muse, mutect2, varscan2
- KCNA7 | c.843A>T p.R281= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV99672077; called by muse, mutect2, varscan2
- PLPP7 | c.573C>T p.A191= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs371238589; called by muse, mutect2, varscan2
- PLPPR1 | c.957G>A p.A319= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs371737348; called by muse, mutect2, varscan2
- SH3PXD2B | c.1254G>A p.P418= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs115528822, COSV100288651; called by muse, mutect2, varscan2
- GSPT1 | c.-63+218G>T | Intron (SNP) | VAF 13/24 reads (54%) | catalogued as COSV101341780; called by muse, mutect2, varscan2
- NEBL | c.164+46469G>A | Intron (SNP) | VAF 19/23 reads (83%) | catalogued as COSV101008854; called by muse, mutect2, varscan2
